Gene-level copy-number profile of tumor specimen TARGET-40-PAUXPZ-01A from TARGET case TARGET-40-PAUXPZ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.3 years (4,507 days).
Specimen TARGET-40-PAUXPZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.621fe1b4-b027-57bf-9d94-d8ac994f35ee.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAUXPZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 402 have no estimate.
https://portal.gdc.cancer.gov/files/9c728923-12b2-43e5-aa6e-2aa1877045c0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 312; copy number 2: 13,241; copy number 3: 7,460; copy number 4: 26,642; copy number 5: 4,989; copy number 6: 4,724; copy number 7: 2,304; copy number 20: 14.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr7:147,080,934–147,378,121, 4 genes: CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr11:84,545,131–84,800,701, 3 genes (within-gene range 0–1): HNRNPA1P72, AP000852.1, AP001825.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,885,397–89,046,466, 14 genes, copy number 20: IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.

Autosomal genes at a single copy (total copy number 1): 312. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
